Somatic mutation profile of tumor specimen 0DEAZ3 from CCDI case PBBPGL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,560 days).
Specimen 0DEAZ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf4be262-f6a9-42f6-baa1-dfb5f1aba542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEAYS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbdf2d50-49a1-48a2-859b-0cb36ae6c837

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 158/650 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MGAM2 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 145/761 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as rs569896212; called by muse, mutect2, varscan2
- PTH1R | c.1312C>A p.Q438K | Missense Mutation (SNP) | VAF 54/507 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV100480956; called by muse, mutect2, varscan2
- PIEZO1 | c.1999C>T p.L667= | Splice Region (SNP) | VAF 40/1296 reads (3%) | called by muse, mutect2
- TNS2 | c.2094G>A p.A698= (on ENST00000314250 / NM_170754.4; = p.A708= on NM_015319.2) | Silent (SNP) | VAF 79/535 reads (15%) | catalogued as rs750361084, COSV56853700; called by muse, mutect2, varscan2
- TRPM5 | c.2925C>T p.I975= | Silent (SNP) | VAF 93/855 reads (11%) | catalogued as rs368821972; called by muse, mutect2, varscan2
